Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5GA, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5GA-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site: @Lung, upper lobe
C34.1

JA 2/7/13

Histopathology Report

SUPPLEMENTARY REPORT BELOW (22/2)

HISTORY

L U lobectomy. Past history Hutchinson's melanotic freckle.

MACROSCOPIC

Two specimens received

1: The specimen is labelled 'left upper lobe' and consists of a lobectomy specimen measuring in its partially inflated state 210 x 150 x 50 mm. Two separate bronchi are seen at the hilum ranging in size from 10 to 12 mm in diameter (lying approximately 30 mm apart). Surrounding the two bronchi is a bare area measuring 55 mm in maximal diameter. A staple line is seen radiating from the hilar to the periphery, it measures 80 mm in length. Differential inking is as follows, the bare area is inked black and the staple line is removed and inked blue. The pleural surface is tan to grey with a diffuse area of induration over the lateral lower aspect of the lobe extending over the lingular, which measures 60 mm in greatest dimension. There is also scarring over the apex measuring 15 mm in greatest dimension. The cut surface of the lung shows a centrally based/peri-bronchial tumour measuring 35 mm in greatest dimension. It extends peripherally to focally abut the pleural surface (posterior lateral). Definite macroscopic invasion of the pleura is not seen. The tumour has a white firm cut surface with focal areas of necrosis. It lies 10 mm from the closest bronchial margin. A second firm tan nodule measuring 6 mm in greatest dimension in the apical portion of the lobe. It lies 2 mm from the pleural surface (appears to abut the pleural surface) and over 70 mm to the bronchial margin and 65 mm from the main tumour mass. There is normal intervening lung. The residual lung shows moderate to severe emphysema and an area of pleurally based fibrosis adjacent to the induration over the lingular/lateral surface. [1A, bronchial margin; 1B, hilar lymph nodes; 1C-D, TS through tumour with 1C including closest bronchial margin and 1D showing extension to pleura; 1E-F, RS of tumour abutting pleural surface; 1G, second possible tumour within apical aspect of lobe; 1H, RS of normal intervening lung between main tumour mass and smaller tumour; 1I, peri-bronchial lymph nodes; 1J, area of fibrosis over lateral/lingular pleura; 1K, RS of emphysema within upper portion of lobe]

2: The specimen is labelled 'hilar lymph node left lung' and consists of over ten fragments of what appears to be nodal tissue ranging in size from 2 mm to the largest piece measuring 20 mm in greatest dimension. The fragments have a grey black cut surface. [BIT: 2A, largest piece bisected; 2B, multiple smaller fragments]

MICROSCOPIC

1: Sections reveal a moderate and poorly differentiated squamous cell

[page 2 of 3]
carcinoma. The tumour abuts but does not invade visceral pleura. The tumour is clear of the bronchial resection margin. Within the confines of the tumour there is focal vascular and lymphatic invasion. No perineural permeation by tumour is seen. Peribronchial lymph nodes show reactive changes with sinus histiocytosis, carbon pigment deposition and scattered flecks of birefringent material in keeping with silicate. No tumour is identified within these nodes. Immediately adjacent to the tumour there is focal change within lung parenchyma in keeping with obstructive pneumonitis characterised by focal organising pneumonia, mild acute alveolitis, and a few collections of intra-alveolar foamy macrophages. Marked emphysema is present. Associated with a mixed dust macule there is a small non-necrotising granuloma. The separately described macroscopic lesions represent foci of scarring and organising pneumonia. No tumour is identified within these areas.

2: Sections of lymph node tissue reveal reactive changes with prominent sinus histiocytosis, carbon pigment deposition and scattered flecks of birefringent material in keeping with silicate. Reactive follicular hyperplasia is also noted. Rare tiny ill-defined non-necrotising granulomata are also seen focally. There is no evidence of malignancy.

SUMMARY

1&2: Left upper lobectomy with separately submitted left hilar lymph node: Moderately and poorly differentiated squamous cell carcinoma.

Tumour size 35 mm in diameter.

No visceral pleural invasion seen.

Bronchial resection margin clear of tumour.

Focal lymphatic and vascular invasion present within tumour.

Peribronchial lymph nodes and separately submitted hilar lymph node not involved by tumour.

Pathological stage: pT2a N0.

Emphysema, separate focal areas of scarring and organising pneumonia.

Reported

T-28000 M-80703 P1-03000

SUPPLEMENTARY REPORT

No micro-organisms are identified with special stains (Ziehl-Neelsen, Grocott, PAS; sections 1C and 2A).

[page 3 of 3]
ANATOMICAL PATHOLOGY

Source: NCI Genomic Data Commons file 7a8c62c8-d4f5-418a-9f6e-4d6f0cee78fa (TCGA-77-A5GA.98FCB868-1962-4738-868A-8F4958F27469.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).